Gene-level copy-number profile of specimen HCM-BROD-0044-C15-85B from HCMI case HCM-BROD-0044-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 36.1 years (13,168 days).
Specimen HCM-BROD-0044-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b7891f03-aa02-44ba-8f8f-e60352bbb941.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0044-C15-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/acab90c8-6246-481a-96d8-5059af31b165

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,640; copy number 2: 17,543; copy number 3: 25,242; copy number 4: 9,938; copy number 5: 2,784; copy number 6: 665; copy number 7: 551; copy number 8: 126; copy number 9: 223; copy number 10: 88; copy number 11: 50; copy number 12: 40; copy number 13: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,084 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,754,301–154,155,116, 256 genes, copy number 7 (broad region; genes not listed).
- chr1:158,694,539–160,711,831, 86 genes, copy number 7 (broad region; genes not listed).
- chr6:84,019,204–84,227,643, 3 genes, copy number 7: LINC02857, MRAP2, CEP162.
- chr7:63,209,219–63,248,321, 4 genes, copy number 8: AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4.
- chr7:92,457,564–92,590,393, 6 genes, copy number 7–8 (within-gene range 4–8): AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B.
- chr7:102,813,230–103,162,660, 12 genes, copy number 7: FBXL13, RNU6-1136P, RN7SKP198, LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3.
- chr7:103,297,435–103,514,007, 8 genes, copy number 7 (within-gene range 4–7): PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1.
- chr7:103,484,208–103,484,539, 1 gene, copy number 7 (within-gene range 4–7): RN7SKP86.
- chr9:26,796,173–28,888,955, 30 genes, copy number 7–12: AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873.
- chr9:29,317,833–37,465,450, 226 genes, copy number 7–9 (broad region; genes not listed).
- chr9:60,914,407–61,453,030, 12 genes, copy number 7–9: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:64,637,845–64,765,535, 4 genes, copy number 11: AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr9:64,817,870–64,836,341, 1 gene, copy number 7: AL359955.1.
- chr9:65,189,995–65,250,826, 4 genes, copy number 8: BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1.
- chr10:31,033,089–31,320,447, 4 genes, copy number 7 (within-gene range 5–7): AL359546.1, LINC02664, ZEB1-AS1, RNA5SP309.
- chr11:61,429,220–62,679,117, 68 genes, copy number 8–12 (within-gene range 4–12) (broad region; genes not listed).
- chr11:66,744,451–66,843,516, 1 gene, copy number 12 (within-gene range 2–12): C11orf80.
- chr11:66,842,835–67,050,863, 8 genes, copy number 9–12: RCE1, PC, LRFN4, RNU7-23P, MIR3163, C11orf86, SYT12, MIR6860.
- chr11:69,641,156–71,252,577, 37 genes, copy number 11–13: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:71,865,509–71,928,654, 1 gene, copy number 9 (within-gene range 6–9): AP002495.1.
- chr11:71,893,410–71,904,081, 2 genes, copy number 9: OR7E128P, OR7E126P.
- chr16:35,192,687–35,912,516, 65 genes, copy number 7–9 (broad region; genes not listed).
- chr17:37,514,807–41,865,423, 233 genes, copy number 8–11 (broad region; genes not listed).
- chr21:14,236,206–15,014,430, 11 genes, copy number 10–12 (within-gene range 3–12): ABCC13, HSPA13, SAMSN1, SAMSN1-AS1, AF127936.1, POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3.
- chr21:14,961,309–14,964,233, 1 gene, copy number 10 (within-gene range 3–10): AF127577.1.

Autosomal genes at a single copy (total copy number 1): 1,640. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
